Somatic mutation profile of tumor specimen C3L-06017-01 (aliquot CPT0361500009) from CPTAC case C3L-06017, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 72.2 years (26,380 days).
Specimen C3L-06017-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b5801da-eb0b-4031-b856-0389d2caaef7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06017-31 (Blood Derived Normal), aliquot CPT0361600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a1105d2-9074-4b93-b516-e1c079226dad

The open-access MAF lists 568 somatic variants for this specimen: 359 protein-altering or splice-affecting, 184 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 326, Silent 184, Nonsense Mutation 23, Intron 12, 5'UTR 5, Splice Site 4, Splice Region 3, 3'UTR 3, Frame Shift Del 3, 5'Flank 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACTR10 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 106/265 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs768311278; called by muse, mutect2, varscan2
- ADAM11 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 111/369 reads (30%) | catalogued as COSV52347765; called by mutect2, varscan2
- ADAM29 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63660843, COSV63663413; called by muse, mutect2, varscan2
- ADAMTS7 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 86/432 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66308118; called by muse, varscan2
- ALPK2 | c.4847G>A p.G1616E | Missense Mutation (SNP) | VAF 123/361 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV64492252; called by muse, mutect2, varscan2
- AP3B1 | c.2501C>T p.P834L | Missense Mutation (SNP) | VAF 130/240 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs771038183; called by muse, mutect2, varscan2
- APC | c.2054G>A p.W685* | Nonsense Mutation (SNP) | VAF 45/268 reads (17%) | catalogued as COSV57372881; called by muse, mutect2, varscan2
- APC | c.3247G>A p.D1083N | Missense Mutation (SNP) | VAF 81/378 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); catalogued as COSV57320846; called by muse, mutect2, varscan2
- APC | c.3381G>T p.Q1127H | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as rs1554084977; ClinVar: uncertain significance; called by mutect2, varscan2
- APC | c.4456G>A p.D1486N | Missense Mutation (SNP) | VAF 85/331 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57338408, COSV57359679, COSV57381661, COSV57404183; called by muse, mutect2, varscan2
- APC | c.6998del p.R2333Kfs*4 | Frame Shift Del (DEL) | VAF 118/312 reads (38%) | catalogued as COSV57376297; called by pindel, varscan2
- AQP7 | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 113/240 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV53003304; called by muse, mutect2, varscan2
- AR | c.1757G>A p.R586K | Missense Mutation (SNP) | VAF 141/212 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM931182; called by muse, mutect2, varscan2
- ARHGAP20 | c.501C>A p.F167L | Missense Mutation (SNP) | VAF 113/275 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs770595466; called by muse, mutect2, varscan2
- ASTN2 | c.2324G>A p.G775E (on ENST00000313400 / NM_001365069.1; = p.G724E on NM_014010.5) | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV57767414; called by muse, mutect2, varscan2
- ATP13A4 | c.2135G>A p.R712K | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV61318372, COSV61328200; called by muse, mutect2, varscan2
- BMPER | c.1607G>A p.R536K | Missense Mutation (SNP) | VAF 84/489 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV51832711; called by muse, mutect2, varscan2
- BRINP3 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 194/407 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs267598250, COSV66527745; called by muse, mutect2, varscan2
- CACNG3 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 211/511 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.653); catalogued as COSV50079592; called by muse, mutect2, varscan2
- CBL | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867564832, COSV50631687, COSV50635445; called by muse, varscan2
- CD320 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 163/540 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV56848721; called by muse, mutect2, varscan2
- CDH16 | c.2168G>A p.G723D | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs142206322, COSV55336723; called by muse, mutect2, varscan2
- CEP350 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780482124; called by muse, mutect2, varscan2
- CFAP46 | c.4478G>A p.G1493E | Missense Mutation (SNP) | VAF 85/336 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1404742689; called by muse, mutect2, varscan2
- CFAP47 | c.8845C>T p.P2949S | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as rs1436427218, COSV66220766; called by muse, mutect2, varscan2
- CFH | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV62777161; called by muse, mutect2, varscan2
- CHRNB3 | c.129G>A p.W43* | Nonsense Mutation (SNP) | VAF 63/483 reads (13%) | catalogued as rs749944493; called by muse, mutect2, varscan2
- CIDEA | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1278609663, COSV57597111; called by muse, mutect2, varscan2
- CNGB3 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 204/602 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs757716046, COSV60695396; called by muse, mutect2, varscan2
- CNTN4 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs374090181; called by muse, mutect2, varscan2
- COL11A2 | c.2519G>A p.R840Q (on ENST00000341947 / NM_080680.3; = p.R733Q on NM_080679.2) | Missense Mutation (SNP) | VAF 253/746 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs538425732, COSV100554657; called by muse, mutect2, varscan2
- COL21A1 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs764079345; called by muse, mutect2, varscan2
- COL5A2 | c.1870G>A p.G624S | Missense Mutation (SNP) | VAF 75/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66406646, COSV66407395; called by muse, mutect2, varscan2
- CRYBB1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 96/389 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs374176492; called by muse, mutect2, varscan2
- CSMD3 | c.1462G>A p.D488N (on ENST00000297405 / NM_001363185.1; = p.D384N on NM_052900.3) | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52119159; called by muse, mutect2, varscan2
- DAO | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 123/415 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs150760302; called by muse, mutect2, varscan2
- DLX5 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 69/511 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56032639; called by muse, mutect2, varscan2
- DMC1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 67/281 reads (24%) | catalogued as rs1300163639, COSV53258029; called by muse, mutect2, varscan2
- DNAH14 | c.5198C>T p.S1733F (on ENST00000445597; = p.S2138F on NM_001367479.1) | Missense Mutation (SNP) | VAF 63/314 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV70544069; called by muse, mutect2, varscan2
- DNAH6 | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761847218, COSV52862492; called by muse, mutect2, varscan2
- DNAJA4 | c.585G>C p.E195D (on ENST00000343789; = p.E224D on NM_018602.3) | Missense Mutation (SNP) | VAF 76/462 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59426625; called by muse, varscan2
- DSEL | c.2952G>A p.M984I | Missense Mutation (SNP) | VAF 64/513 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs770634593, COSV59490224; called by muse, mutect2, varscan2
- DSPP | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.006); catalogued as COSV104390375; called by muse, mutect2, varscan2
- EBF2 | c.1547C>T p.T516I | Missense Mutation (SNP) | VAF 102/325 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as rs748485575, COSV68779484; called by muse, varscan2
- EBF3 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs1355009922; called by muse, mutect2, varscan2
- EEF1A2 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 84/557 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs1355004578, COSV53206172; called by muse, mutect2, varscan2
- EFCAB6 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 75/403 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs146118090; called by muse, mutect2, varscan2
- ELANE | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 214/583 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD135463, CM135464, CM153477; called by muse, mutect2, varscan2
- ENDOV | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548277311; called by muse, mutect2, varscan2
- ENPEP | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as COSV54451225; called by muse, mutect2, varscan2
- FAM83B | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 136/422 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60920410; called by muse, mutect2, varscan2
- FRAS1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs765229421; called by muse, mutect2, varscan2
- FSHR | c.594G>A p.L198= | Splice Region (SNP) | VAF 94/240 reads (39%) | catalogued as rs767937801; called by muse, mutect2, varscan2
- GABRQ | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 129/171 reads (75%) | catalogued as COSV64780934; called by muse, mutect2, varscan2
- GALNT17 | c.1669-1G>A p.X557_splice | Splice Site (SNP) | VAF 67/205 reads (33%) | catalogued as COSV61168513; called by muse, mutect2, varscan2
- GCKR | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 115/264 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.099); catalogued as rs1197591803, COSV53022323; called by muse, mutect2, varscan2
- GDF5 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 124/663 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV100976751, COSV65503916; called by muse, mutect2, varscan2
- GRIA2 | c.1777G>T p.G593W | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99645404; called by muse, mutect2, varscan2
- HEATR1 | c.5314C>T p.P1772S | Missense Mutation (SNP) | VAF 66/522 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); catalogued as rs758655047, COSV100857846; called by muse, mutect2, varscan2
- HOXA4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 111/356 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57825200; called by muse, mutect2, varscan2
- HTR1A | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 233/434 reads (54%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); catalogued as COSV60500871; called by muse, mutect2, varscan2
- IL31RA | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 106/196 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771476993; called by muse, mutect2, varscan2
- ITGAL | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.213); catalogued as rs1449664297, COSV63323681; called by muse, mutect2, varscan2
- JAKMIP3 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 123/390 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs772360908; called by muse, mutect2, varscan2
- JHY | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 71/399 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs1321673514; called by muse, mutect2, varscan2
- KDR | c.3847G>T p.G1283C | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV99817269; called by muse, mutect2, varscan2
- KIAA1217 | c.5189C>T p.S1730L | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); catalogued as rs1189512254, COSV56812591; called by muse, mutect2, varscan2
- KIR3DL2 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as rs372086523; called by muse, varscan2
- KRTAP13-4 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 73/420 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.829); catalogued as rs76547537, COSV61879152; called by muse, mutect2, varscan2
- LNX1 | c.1751C>T p.S584L (on ENST00000263925 / NM_001126328.3; = p.S488L on NM_032622.2) | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs533306649, COSV55791732; called by muse, mutect2, varscan2
- LOXHD1 | c.2870C>T p.S957L | Missense Mutation (SNP) | VAF 125/349 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1440105492; called by muse, mutect2, varscan2
- LOXHD1 | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 149/421 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV59661405; called by muse, mutect2, varscan2
- LRP1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 117/364 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV54511863; called by muse, mutect2, varscan2
- LRP10 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 34/675 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.572); catalogued as rs781458748, COSV62078839; called by muse, mutect2
- MAGEL2 | c.3094T>A p.L1032I | Missense Mutation (SNP) | VAF 76/416 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58566203; called by muse, mutect2, varscan2
- MAP1A | c.5576C>A p.P1859Q | Missense Mutation (SNP) | VAF 90/373 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV55809652; called by muse, mutect2, varscan2
- MAP3K20 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 111/391 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs769862837, COSV64381013; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2, varscan2
- MEGF11 | c.2795C>T p.S932F | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs901128170; called by muse, mutect2, varscan2
- MOV10L1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 82/404 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs952478855; called by muse, mutect2
- MROH2B | c.1647G>A p.W549* | Nonsense Mutation (SNP) | VAF 78/248 reads (31%) | catalogued as COSV68182214, COSV68190008; called by muse, mutect2, varscan2
- MUC16 | c.23722C>T p.H7908Y | Missense Mutation (SNP) | VAF 187/548 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); catalogued as rs1280628050; called by muse, mutect2, varscan2
- MUC4 | c.4561C>T p.L1521F | Missense Mutation (SNP) | VAF 78/441 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.598); catalogued as rs1359364581; called by muse, mutect2, varscan2
- MYBPH | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 149/329 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV104370751; called by muse, mutect2, varscan2
- MYH7 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 16/524 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62517752; called by muse, mutect2
- MYO18B | c.4415G>T p.R1472L | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59128718; called by muse, mutect2, varscan2
- NAA30 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 185/576 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs755417614; called by muse, varscan2
- NCOA3 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 172/468 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.615); catalogued as COSV100507625; called by muse, varscan2
- NEB | c.11560G>A p.D3854N | Missense Mutation (SNP) | VAF 126/354 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752089716, COSV50881854, COSV51436297; called by muse, mutect2, varscan2
- NLRP13 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 118/361 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.192); catalogued as COSV61621954; called by muse, mutect2, varscan2
- NMD3 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs769698988, COSV63618203; called by muse, mutect2, varscan2
- NOC4L | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 104/607 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs749469090; called by muse, mutect2, varscan2
- NOS3 | c.3307G>A p.V1103M | Missense Mutation (SNP) | VAF 47/520 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.859); catalogued as rs765463421, COSV52490614; called by muse, mutect2
- NRXN2 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 130/343 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as rs751415381, COSV55454447; called by muse, mutect2, varscan2
- OLFM3 | c.385C>T p.R129W (on ENST00000338858 / NM_001288821.1; = p.R109W on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/325 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs189154354, COSV58795947; called by muse, mutect2, varscan2
- OR4C15 | c.1085C>T p.S362F (on ENST00000314644; = p.S308F on NM_001001920.2) | Missense Mutation (SNP) | VAF 96/207 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.509); catalogued as rs566059039, COSV58953283; called by muse, mutect2, varscan2
- OR4F15 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 136/376 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs1460634616, COSV100173937; called by muse, mutect2, varscan2
- OR4M2 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60305963; called by mutect2, varscan2
- OR52N4 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 187/424 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs746747156, COSV57890447; called by muse, mutect2, varscan2
- OR5AC2 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 182/488 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV62279154; called by muse, mutect2, varscan2
- PADI3 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1435888322, COSV64933896, COSV64934081; called by muse, mutect2, varscan2
- PDE6A | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 86/153 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54924151; called by muse, mutect2, varscan2
- PEX5L | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 113/365 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.169); catalogued as rs1461387388; called by muse, mutect2, varscan2
- PIDD1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs765584346; called by muse, mutect2, varscan2
- PKLR | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 155/690 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61362497; called by muse, mutect2, varscan2
- PLEK | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.534); catalogued as COSV52252865; called by muse, mutect2, varscan2
- PLEKHM1 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 215/563 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs769164032, COSV69598798; called by muse, mutect2, varscan2
- PPM1J | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1434626270, COSV58552237; called by muse, mutect2, varscan2
- PREX2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 137/434 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV55793590; called by muse, mutect2, varscan2
- PRR23A | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 182/543 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.432); catalogued as rs769267243, COSV67213422; called by muse, mutect2, varscan2
- PRSS35 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 79/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189341775; called by muse, mutect2, varscan2
- PSG5 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV61654835; called by muse, mutect2, varscan2
- PSG5 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 120/464 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV61653914; called by muse, varscan2
- PTK2B | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 68/434 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.024); catalogued as COSV57750997; called by muse, mutect2
- PTPRB | c.4366C>T p.R1456C | Missense Mutation (SNP) | VAF 141/421 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1220260066; called by muse, mutect2, varscan2
- PTPRD | c.3073C>T p.H1025Y | Missense Mutation (SNP) | VAF 103/198 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV61938506, COSV61959330; called by muse, mutect2, varscan2
- PTPRT | c.3602G>A p.R1201Q | Missense Mutation (SNP) | VAF 159/418 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372862828, COSV100631324, COSV61969750; called by muse, mutect2, varscan2
- R3HCC1 | c.421C>T p.P141S (on ENST00000411463; = p.P101S on NM_001136108.3) | Missense Mutation (SNP) | VAF 252/735 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.511); catalogued as COSV56120779; called by muse, mutect2, varscan2
- RABGGTA | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 92/505 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs749256354, COSV53770239; called by muse, mutect2, varscan2
- RALGPS2 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 59/281 reads (21%) | catalogued as COSV62678628, COSV62678803; called by muse, mutect2, varscan2
- RARA | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 96/336 reads (29%) | catalogued as COSV54194127; called by muse, varscan2
- RGPD3 | c.2953C>T p.Q985* | Nonsense Mutation (SNP) | VAF 198/625 reads (32%) | catalogued as rs1253222842, COSV100450453; called by muse, mutect2, varscan2
- RIMS2 | c.4252G>A p.D1418N (on ENST00000666250 / NM_001348490.2; = p.D989N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 129/432 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51721268; called by muse, mutect2, varscan2
- RIPK4 | c.1756C>T p.R586W (on ENST00000352483; = p.R538W on NM_020639.3) | Missense Mutation (SNP) | VAF 190/579 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.076); catalogued as rs370433302; called by muse, mutect2, varscan2
- RND1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 155/439 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs144289367; called by muse, mutect2, varscan2
- RTL1 | c.3023A>T p.N1008I | Missense Mutation (SNP) | VAF 147/473 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.013); catalogued as COSV66017470; called by muse, mutect2, varscan2
- S1PR3 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 112/208 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63981423; called by muse, mutect2, varscan2
- SALL3 | c.2795C>T p.P932L | Missense Mutation (SNP) | VAF 243/726 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs753368702, COSV101610033; called by muse, mutect2, varscan2
- SAMD14 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 81/428 reads (19%) | catalogued as rs377222727; called by muse, mutect2, varscan2
- SAXO2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 103/309 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149603065, COSV59753430; called by muse, mutect2, varscan2
- SCARB1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 157/549 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55549911; called by muse, mutect2, varscan2
- SCART1 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 128/535 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as rs576078356; called by muse, mutect2, varscan2
- SCN4A | c.4882G>A p.D1628N | Missense Mutation (SNP) | VAF 66/509 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1004398583, COSV71127632; called by muse, mutect2
- SH3BGRL2 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs769605394; called by muse, mutect2, varscan2
- SIRPG | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 140/403 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs1178495642; called by muse, mutect2, varscan2
- SLC4A10 | c.3037-1G>A p.X1013_splice (on ENST00000446997 / NM_001354461.2; = p.X983_splice on NM_022058.4 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 50/166 reads (30%) | catalogued as COSV55764948, COSV55796166; called by muse, mutect2, varscan2
- SMARCC1 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as COSV54383030, COSV54387771; called by muse, mutect2, varscan2
- SNTG1 | c.676A>T p.S226C | Missense Mutation (SNP) | VAF 13/350 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52474937; called by muse, mutect2
- SRGN | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424053609, COSV54344881; called by muse, mutect2, varscan2
- STAB2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 156/472 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs139925581; called by muse, mutect2, varscan2
- STMN2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 124/560 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs267602010; called by muse, mutect2, varscan2
- STON2 | c.2419G>A p.E807K (on ENST00000649389 / NM_001366849.2; = p.E750K on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/517 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs1190601443, COSV99964713; called by muse, mutect2, varscan2
- STYXL1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 59/401 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs142991497; called by muse, mutect2, varscan2
- TAGAP | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 93/170 reads (55%) | catalogued as rs1444753345; called by muse, mutect2, varscan2
- TAS2R41 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 121/343 reads (35%) | catalogued as COSV68764952; called by muse, mutect2, varscan2
- TENM3 | c.6853G>A p.E2285K | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101305314; called by muse, mutect2, varscan2
- TEX15 | c.2473C>A p.Q825K (on ENST00000256246; = p.Q1208K on NM_001350162.2) | Missense Mutation (SNP) | VAF 70/411 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.363); catalogued as COSV99822367; called by muse, mutect2, varscan2
- THSD7B | c.2378C>T p.S793F | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs1347902701, COSV55656405; called by muse, mutect2, varscan2
- TJP3 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 220/672 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs144472063; called by muse, mutect2, varscan2
- TLN2 | c.5546G>A p.G1849E | Missense Mutation (SNP) | VAF 50/375 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.489); catalogued as COSV100169642; called by muse, mutect2, varscan2
- TMPRSS13 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 106/527 reads (20%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.149); catalogued as rs760471305; called by muse, mutect2, varscan2
- TNKS1BP1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 109/529 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100836135; called by muse, mutect2, varscan2
- TNXB | c.8242G>A p.E2748K (on ENST00000647633; = p.E2501K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/301 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1274678608, COSV64491661; called by muse, mutect2, varscan2
- TPTE2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 53/303 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs140148307; called by muse, mutect2, varscan2
- TRIM49C | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 109/304 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV101442248; called by muse, mutect2, varscan2
- TRIM58 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 169/377 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100824782, COSV63569425; called by muse, mutect2, varscan2
- TRRAP | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 112/413 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs147405090, COSV62839126, COSV62849075; called by muse, mutect2, varscan2
- TTLL10 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 138/494 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1161274857; called by muse, varscan2
- TTN | c.34540G>A p.E11514K (on ENST00000591111; = p.E10587K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/167 reads (28%) | PolyPhen benign (0.003); catalogued as COSV100592657; called by muse, mutect2, varscan2
- TTN | c.30362G>A p.R10121Q (on ENST00000591111; = p.R9194Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/166 reads (19%) | PolyPhen benign (0.012); catalogued as rs778655704; called by muse, varscan2
- UBASH3A | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 190/567 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.887); catalogued as rs774781107, COSV52313659; called by muse, mutect2, varscan2
- USHBP1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 58/395 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as COSV53102322; called by muse, mutect2, varscan2
- VSIG10 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 59/536 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs766167150; called by muse, mutect2, varscan2
- WASF3 | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 36/186 reads (19%) | catalogued as rs1465923845, COSV58963978; called by muse, mutect2, varscan2
- WDR87 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 148/465 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58199289; called by muse, mutect2
- WIF1 | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54132253; called by muse, mutect2, varscan2
- WNT7A | c.939C>A p.Y313* | Nonsense Mutation (SNP) | VAF 61/316 reads (19%) | catalogued as rs759942290; called by muse, mutect2, varscan2
- ZBED2 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 135/430 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as rs149742663; called by muse, mutect2, varscan2
- ZBTB41 | c.2659C>T p.L887F | Missense Mutation (SNP) | VAF 189/431 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66358857; called by muse, mutect2, varscan2
- ZFC3H1 | c.3763C>T p.R1255* | Nonsense Mutation (SNP) | VAF 44/253 reads (17%) | catalogued as rs1410832421, COSV66430052; called by muse, mutect2, varscan2
- ZFHX3 | c.1843G>T p.G615C | Missense Mutation (SNP) | VAF 108/570 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs374656443; called by muse, mutect2
- ZFHX4 | c.6062C>T p.S2021F | Missense Mutation (SNP) | VAF 178/494 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs1563561100; called by muse, mutect2, varscan2
- ZHX2 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 106/554 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100073639; called by muse, mutect2, varscan2
- ZNF397 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 107/343 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99735099; called by muse, mutect2, varscan2
- ZNF727 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs779969086; called by muse, mutect2, varscan2
- ZNF831 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 150/492 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.284); catalogued as rs1027337822; called by muse, varscan2
- ZNF91 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV56082916; called by muse, mutect2, varscan2
- ADAM18 | c.1739C>T p.S580F | Missense Mutation (SNP) | VAF 152/536 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS1 | c.190_192delinsAA p.E64Nfs*66 | Frame Shift Del (DEL) | VAF 159/644 reads (25%) | called by pindel, varscan2*
- ADAMTSL5 | c.550G>C p.G184R | Missense Mutation (SNP) | VAF 95/498 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADGRV1 | c.16972G>A p.E5658K | Missense Mutation (SNP) | VAF 178/334 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ANO1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 96/234 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, varscan2
- ANO8 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 92/596 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO9 | c.1291A>C p.T431P | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- APBA1 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 77/351 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APC | c.2968G>A p.D990N | Missense Mutation (SNP) | VAF 78/331 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- APOL6 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 124/325 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ARID3A | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 76/444 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARMC4 | c.1727G>A p.G576E | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ARNT2 | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 76/526 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ASPM | c.2966G>T p.W989L | Missense Mutation (SNP) | VAF 123/391 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ATP13A5 | c.1739C>A p.P580Q | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIN2 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 142/508 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- C2CD3 | c.6350C>T p.P2117L | Missense Mutation (SNP) | VAF 145/396 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- C2CD3 | c.6349C>T p.P2117S | Missense Mutation (SNP) | VAF 147/398 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CAPN14 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 79/235 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP76 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CEP76 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CEP89 | c.428T>G p.V143G | Missense Mutation (SNP) | VAF 75/478 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHMP6 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 181/464 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- CHTF18 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 99/458 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLIP1 | c.1640C>T p.S547F (on ENST00000620786 / NM_001247997.1; = p.S536F on NM_002956.2) | Missense Mutation (SNP) | VAF 72/405 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- COL1A1 | c.2528C>A p.P843H | Missense Mutation (SNP) | VAF 184/552 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- COL5A3 | c.4075C>T p.L1359F | Missense Mutation (SNP) | VAF 211/519 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL6A5 | c.4967C>T p.P1656L | Missense Mutation (SNP) | VAF 115/349 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- COMMD10 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 179/291 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CPA5 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 112/328 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPD | c.3631del p.X1211_splice | Splice Site (DEL) | VAF 75/202 reads (37%) | called by mutect2, pindel, varscan2
- CPNE2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CRISPLD2 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2
- CRISPLD2 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.362); called by muse, mutect2
- CSGALNACT2 | c.1286A>G p.D429G | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CTSZ | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 199/576 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- DCAF4L1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- DDHD1 | c.1814C>T p.P605L (on ENST00000323669; = p.P802L on NM_030637.3) | Missense Mutation (SNP) | VAF 135/423 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DDX51 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 254/646 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- DENND3 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 87/513 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DGKI | c.2497+1G>A p.X833_splice | Splice Site (SNP) | VAF 89/352 reads (25%) | called by muse, mutect2, varscan2
- DHX16 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 186/570 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- DHX57 | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 107/262 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIO2 | c.225G>A p.V75= | Splice Region (SNP) | VAF 84/268 reads (31%) | called by muse, mutect2
- DLC1 | c.1673C>T p.P558L (on ENST00000276297 / NM_001348081.2; = p.P121L on NM_006094.5) | Missense Mutation (SNP) | VAF 193/565 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNA2 | c.294T>G p.H98Q | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH10 | c.11891G>A p.G3964E (on ENST00000409039; = p.G3903E on NM_207437.3) | Missense Mutation (SNP) | VAF 95/524 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DNAJA4 | c.480G>C p.Q160H (on ENST00000343789; = p.Q189H on NM_018602.3) | Missense Mutation (SNP) | VAF 87/477 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, varscan2
- DOC2B | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 70/383 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2H1 | c.11902T>G p.S3968A | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, varscan2
- EBF2 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 151/438 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGFL6 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 202/279 reads (72%) | SIFT tolerated (0.35); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- EGFL6 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- EIF3F | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 62/321 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ELOF1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 98/533 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- EPHB4 | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 205/629 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- EPS8L2 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 189/316 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ETF1 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 137/345 reads (40%) | called by muse, mutect2, varscan2
- FAM135B | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM13C | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 93/340 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- FAM90A1 | c.1063C>A p.Q355K | Missense Mutation (SNP) | VAF 95/636 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- FBLIM1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLVCR1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 187/800 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FSD2 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 143/466 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSD2 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 142/463 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- FSIP2 | c.11732C>T p.S3911F | Missense Mutation (SNP) | VAF 93/336 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FSIP2 | c.14494G>A p.E4832K | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- GAL3ST3 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 138/615 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GALNT11 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 87/465 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GCFC2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 111/593 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCNT4 | c.32C>A p.T11N | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GDAP1L1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 127/421 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GLI2 | c.2530G>A p.D844N (on ENST00000361492 / NM_001374353.1; = p.D861N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 151/738 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- GLI3 | c.4643C>T p.P1548L | Missense Mutation (SNP) | VAF 70/442 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GMIP | c.2644C>T p.H882Y | Missense Mutation (SNP) | VAF 193/672 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- GOLGA3 | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 120/362 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTF2E1 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 99/465 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HYDIN | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFT74 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- IMMT | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 84/436 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCTD9 | c.262A>T p.T88S | Missense Mutation (SNP) | VAF 110/407 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF13B | c.4759G>A p.D1587N | Missense Mutation (SNP) | VAF 106/700 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- KIF21B | c.3617C>T p.P1206L | Missense Mutation (SNP) | VAF 144/422 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- KLK7 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 143/399 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KMT2D | c.7837C>T p.P2613S | Missense Mutation (SNP) | VAF 225/647 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KRT16 | c.534C>T p.I178= | Splice Region (SNP) | VAF 110/329 reads (33%) | called by muse, mutect2, varscan2
- LHCGR | c.1828C>T p.L610F | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- LHCGR | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMBRD2 | c.681T>G p.Y227* | Nonsense Mutation (SNP) | VAF 134/262 reads (51%) | called by muse, mutect2, varscan2
- LRFN2 | c.2116G>C p.A706P | Missense Mutation (SNP) | VAF 125/741 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LRP1B | c.9493C>T p.Q3165* | Nonsense Mutation (SNP) | VAF 121/351 reads (34%) | called by muse, mutect2, varscan2
- MDN1 | c.5683C>T p.P1895S | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MEAK7 | c.941T>G p.V314G | Missense Mutation (SNP) | VAF 128/318 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- MGAM | c.4358G>T p.R1453M | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, varscan2
- MGRN1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIGA2 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- MORC2 | c.658C>T p.P220S (on ENST00000397641 / NM_001303256.3; = p.P158S on NM_014941.3) | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- MTMR11 | c.1405C>T p.P469S (on ENST00000439741 / NM_001145862.2; = p.P397S on NM_181873.3) | Missense Mutation (SNP) | VAF 207/442 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- MUC15 | c.173A>G p.D58G | Missense Mutation (SNP) | VAF 146/348 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NBPF12 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by mutect2, varscan2
- NCAM1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 153/383 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NDST2 | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 108/375 reads (29%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NFX1 | c.606T>G p.D202E | Missense Mutation (SNP) | VAF 91/327 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOTCH3 | c.3271C>A p.Q1091K | Missense Mutation (SNP) | VAF 89/641 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOVA1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 78/434 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- NR5A2 | c.415C>T p.P139S (on ENST00000367362 / NM_205860.3; = p.P93S on NM_003822.5) | Missense Mutation (SNP) | VAF 169/373 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR52B4 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- OR5G3 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 108/288 reads (38%) | called by muse, mutect2, varscan2
- OR7D4 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OS9 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 63/354 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTX2 | c.524A>T p.Y175F (on ENST00000408990 / NM_172337.3; = p.Y183F on NM_021728.4) | Missense Mutation (SNP) | VAF 225/610 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- PAPPA2 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 106/521 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PDE1C | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 146/434 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PGAP4 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 182/381 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PGAP6 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 69/429 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- PGLYRP4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 111/419 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLXNA4 | c.3670G>T p.G1224W | Missense Mutation (SNP) | VAF 63/394 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPIE | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 146/285 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- PPIF | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPM1N | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 128/383 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROKR1 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMD1 | c.2834C>A p.P945Q | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PSMD8 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 178/544 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- PTPRJ | c.997_1004del p.V333Rfs*36 | Frame Shift Del (DEL) | VAF 85/439 reads (19%) | called by mutect2, pindel, varscan2
- PXDNL | c.2651G>A p.R884Q | Missense Mutation (SNP) | VAF 73/506 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYGO2 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 174/784 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.041); called by muse, varscan2
- PYGO2 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 175/786 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- RAB23 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- RCE1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 15/526 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- RGPD4 | c.4150A>G p.I1384V | Missense Mutation (SNP) | VAF 155/498 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- RGS6 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 36/393 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- RIMBP2 | c.2398C>T p.H800Y | Missense Mutation (SNP) | VAF 121/382 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- RYK | c.1220G>A p.G407E (on ENST00000620660 / NM_001005861.2; = p.G404E on NM_002958.4) | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RYR2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 243/493 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SBK1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- SCAND1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 79/490 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCCPDH | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCUBE1 | c.2857C>T p.P953S | Missense Mutation (SNP) | VAF 75/405 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDK1 | c.932C>G p.T311S | Missense Mutation (SNP) | VAF 50/318 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SGCG | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 79/354 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SHANK2 | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHOC1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIRPB1 | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 165/453 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SLC12A4 | c.1607A>T p.D536V | Missense Mutation (SNP) | VAF 163/348 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC16A12 | c.1184C>A p.P395Q | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC25A29 | c.356G>A p.R119Q (on ENST00000359232 / NM_001039355.3; = p.R53Q on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 215/639 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SLC4A10 | c.3037G>A p.V1013M (on ENST00000446997 / NM_001354461.2; = p.V983M on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC6A5 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC8A2 | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 70/524 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SMLR1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 127/283 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); called by muse, varscan2
- SPOCK1 | c.381G>A p.W127* | Nonsense Mutation (SNP) | VAF 78/354 reads (22%) | called by muse, mutect2, varscan2
- SRFBP1 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 137/259 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYN3 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBX19 | c.713T>G p.V238G | Missense Mutation (SNP) | VAF 117/526 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TCHHL1 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 134/564 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.159); called by muse, varscan2
- TDRD15 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TEX33 | c.809G>A p.G270E (on ENST00000381821 / NM_001163857.2; = p.G185E on NM_178552.4) | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- THOC1 | c.1787A>G p.D596G | Missense Mutation (SNP) | VAF 62/466 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMCO6 | c.446C>A p.P149Q | Missense Mutation (SNP) | VAF 71/391 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM200B | c.566G>T p.W189L | Missense Mutation (SNP) | VAF 133/455 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRAT1 | c.129C>A p.Y43* | Nonsense Mutation (SNP) | VAF 63/253 reads (25%) | called by muse, mutect2, varscan2
- TRIM64C | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TRIML1 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 80/330 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TSGA13 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TTC6 | c.805G>A p.D269N (on ENST00000267368; = p.D1635N on NM_001310135.3) | Missense Mutation (SNP) | VAF 134/393 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TTN | c.11485C>T p.P3829S (on ENST00000591111; = p.P3783S on NM_003319.4) | Missense Mutation (SNP) | VAF 75/455 reads (16%) | called by muse, mutect2, varscan2
- UBR5 | c.3884C>T p.P1295L | Missense Mutation (SNP) | VAF 170/479 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UHRF1BP1L | c.4198C>T p.Q1400* | Nonsense Mutation (SNP) | VAF 171/469 reads (36%) | called by muse, mutect2, varscan2
- USP7 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- VPS45 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 93/424 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWF | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WFDC5 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 177/491 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WNK2 | c.6877G>A p.D2293N | Missense Mutation (SNP) | VAF 77/289 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT9A | c.806C>A p.P269Q | Missense Mutation (SNP) | VAF 146/590 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZBTB39 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 197/626 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ZCCHC4 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF385C | c.469T>C p.F157L | Missense Mutation (SNP) | VAF 134/389 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- ZNF444 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 83/540 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ZNF638 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF729 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 78/209 reads (37%) | called by muse, mutect2, varscan2
- ZSCAN29 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 143/330 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA13 | c.9375C>T p.I3125= | Silent (SNP) | VAF 156/461 reads (34%) | catalogued as rs759576914, COSV71289447; called by muse, mutect2, varscan2
- ADAD1 | c.960C>T p.I320= | Silent (SNP) | VAF 63/192 reads (33%) | catalogued as COSV56643287; called by muse, mutect2, varscan2
- ADAM22 | c.2517G>T p.L839= | Silent (SNP) | VAF 42/301 reads (14%) | called by muse, mutect2, varscan2
- ADCY6 | c.3036C>T p.I1012= | Silent (SNP) | VAF 48/338 reads (14%) | catalogued as rs1227728057; called by muse, varscan2
- ADGRL2 | c.2904A>G p.S968= (on ENST00000370717 / NM_001366005.1; = p.S955= on NM_012302.4) | Silent (SNP) | VAF 94/184 reads (51%) | catalogued as COSV99589662; called by muse, mutect2, varscan2
- AGBL1 | c.2505C>T p.F835= | Silent (SNP) | VAF 106/336 reads (32%) | called by muse, mutect2, varscan2
- AGTR1 | c.613C>T p.L205= | Silent (SNP) | VAF 153/431 reads (35%) | catalogued as COSV62557635; called by muse, mutect2, varscan2
- ALLC | c.1131G>A p.E377= | Silent (SNP) | VAF 142/339 reads (42%) | catalogued as rs1391260223; called by muse, varscan2
- ANKRD24 | c.2181C>T p.T727= | Silent (SNP) | VAF 254/740 reads (34%) | called by muse, mutect2, varscan2
- ANKRD30B | c.2997G>A p.E999= | Silent (SNP) | VAF 55/198 reads (28%) | catalogued as COSV100271489; called by muse, mutect2, varscan2
- APC | c.4218G>A p.Q1406= | Silent (SNP) | VAF 61/347 reads (18%) | catalogued as COSV57332742, COSV57354402, COSV57377402; called by muse, mutect2, varscan2
- APC | c.6864G>A p.Q2288= | Silent (SNP) | VAF 155/314 reads (49%) | called by muse, mutect2, varscan2
- AQP4 | c.150C>T p.L50= | Silent (SNP) | VAF 134/536 reads (25%) | catalogued as rs201758586; called by muse, mutect2
- ARL11 | c.402G>A p.K134= | Silent (SNP) | VAF 69/476 reads (14%) | called by muse, mutect2, varscan2
- ATCAY | c.696C>T p.I232= | Silent (SNP) | VAF 139/416 reads (33%) | catalogued as rs199586367; called by muse, mutect2, varscan2
- BAHCC1 | c.5103C>T p.A1701= | Silent (SNP) | VAF 106/408 reads (26%) | catalogued as rs910560795; called by muse, mutect2, varscan2
- BCAR3 | c.1335G>A p.K445= | Silent (SNP) | VAF 103/478 reads (22%) | called by muse, mutect2, varscan2
- BOD1 | c.504C>T p.P168= | Silent (SNP) | VAF 47/577 reads (8%) | called by muse, mutect2
- C10orf53 | c.471C>T p.Y157= | Silent (SNP) | VAF 37/186 reads (20%) | catalogued as rs775509299; called by muse, mutect2, varscan2
- C2orf16 | c.273G>A p.V91= | Silent (SNP) | VAF 155/370 reads (42%) | catalogued as rs774121965, COSV68841369; called by muse, mutect2, varscan2
- CACNA2D3 | c.3132G>A p.K1044= | Silent (SNP) | VAF 83/262 reads (32%) | called by muse, mutect2, varscan2
- CCN5 | c.567C>T p.P189= | Silent (SNP) | VAF 108/484 reads (22%) | catalogued as rs1433793079; called by muse, mutect2, varscan2
- CEP350 | c.7338C>T p.I2446= | Silent (SNP) | VAF 212/411 reads (52%) | called by muse, mutect2, varscan2
- CES5A | c.144G>T p.L48= | Silent (SNP) | VAF 141/547 reads (26%) | catalogued as COSV99306983; called by muse, mutect2, varscan2
- CFAP46 | c.7038C>T p.F2346= | Silent (SNP) | VAF 64/288 reads (22%) | catalogued as rs762707957, COSV54149009; called by muse, mutect2, varscan2
- CFAP91 | c.1398C>T p.F466= | Silent (SNP) | VAF 87/304 reads (29%) | called by muse, mutect2, varscan2
- CHPF2 | c.1966C>A p.R656= | Silent (SNP) | VAF 110/654 reads (17%) | called by muse, mutect2, varscan2
- CIAO3 | c.411G>A p.R137= | Silent (SNP) | VAF 117/269 reads (43%) | called by muse, mutect2, varscan2
- CNBD1 | c.1251C>T p.I417= | Silent (SNP) | VAF 53/338 reads (16%) | catalogued as rs1477500585; called by muse, mutect2, varscan2
- CNBP | c.246C>T p.H82= | Silent (SNP) | VAF 65/440 reads (15%) | catalogued as rs1387893206; called by muse, mutect2, varscan2
- COL16A1 | c.396C>T p.S132= | Silent (SNP) | VAF 94/190 reads (49%) | called by muse, mutect2, varscan2
- COQ8A | c.111C>T p.I37= | Silent (SNP) | VAF 311/721 reads (43%) | called by muse, mutect2, varscan2
- CPS1 | c.2280C>T p.A760= | Silent (SNP) | VAF 71/408 reads (17%) | catalogued as COSV51812305; called by muse, mutect2, varscan2
- CSNK1G2 | c.948C>T p.F316= | Silent (SNP) | VAF 104/584 reads (18%) | catalogued as rs756723494; called by muse, mutect2, varscan2
- DDR1 | c.2334C>T p.F778= (on ENST00000324771; = p.F741= on NM_001954.4) | Silent (SNP) | VAF 247/724 reads (34%) | called by muse, varscan2
- DEFB1 | c.150G>A p.P50= | Silent (SNP) | VAF 67/482 reads (14%) | catalogued as rs142991753, COSV99858921; called by muse, varscan2
- DHRS7C | c.804G>A p.R268= (on ENST00000330255 / NM_001220493.2; = p.R267= on NM_001105571.3) | Silent (SNP) | VAF 309/491 reads (63%) | catalogued as rs1052170003, COSV100364962; called by muse, mutect2, varscan2
- DLG5 | c.3003C>T p.P1001= | Silent (SNP) | VAF 102/401 reads (25%) | called by muse, mutect2, varscan2
- DNAH14 | c.5199C>T p.S1733= (on ENST00000445597; = p.S2138= on NM_001367479.1) | Silent (SNP) | VAF 63/316 reads (20%) | called by muse, mutect2, varscan2
- DNAH9 | c.4161G>A p.R1387= | Silent (SNP) | VAF 109/497 reads (22%) | catalogued as rs1429926364, COSV99305091; called by muse, mutect2, varscan2
- DPP10 | c.720C>T p.I240= | Silent (SNP) | VAF 111/291 reads (38%) | catalogued as rs753852164, COSV59660437, COSV59681570; called by muse, mutect2, varscan2
- DRC7 | c.930G>A p.G310= | Silent (SNP) | VAF 98/427 reads (23%) | called by muse, mutect2, varscan2
- EBF2 | c.1215C>T p.V405= | Silent (SNP) | VAF 152/440 reads (35%) | called by muse, mutect2, varscan2
- EGR4 | c.411C>A p.A137= (on ENST00000545030; = p.A34= on NM_001965.4) | Silent (SNP) | VAF 101/472 reads (21%) | called by muse, mutect2, varscan2
- EIF2S3B | c.1315C>T p.L439= | Silent (SNP) | VAF 25/246 reads (10%) | called by muse, mutect2, varscan2
- EPB41L4B | c.1419C>T p.L473= | Silent (SNP) | VAF 72/248 reads (29%) | catalogued as COSV65804744; called by muse, mutect2, varscan2
- ERO1A | c.1027T>C p.L343= | Silent (SNP) | VAF 67/188 reads (36%) | called by muse, mutect2, varscan2
- EVPL | c.33G>A p.G11= | Silent (SNP) | VAF 132/439 reads (30%) | called by muse, mutect2, varscan2
- F13A1 | c.1698G>A p.K566= | Silent (SNP) | VAF 176/512 reads (34%) | called by muse, mutect2, varscan2
- FAM178B | c.342C>T p.P114= | Silent (SNP) | VAF 135/762 reads (18%) | catalogued as rs749570709, COSV59969934, COSV59971196; called by muse, mutect2, varscan2
- FAM193A | c.96C>T p.S32= | Silent (SNP) | VAF 105/405 reads (26%) | called by muse, mutect2, varscan2
- FANCB | c.2391C>T p.V797= | Silent (SNP) | VAF 184/282 reads (65%) | catalogued as rs778731279; called by muse, varscan2
- FBLN2 | c.648C>T p.V216= | Silent (SNP) | VAF 82/452 reads (18%) | catalogued as rs1479607587; called by muse, mutect2, varscan2
- FBXO39 | c.621C>T p.H207= | Silent (SNP) | VAF 219/332 reads (66%) | called by muse, mutect2, varscan2
- FGD6 | c.2691C>T p.F897= | Silent (SNP) | VAF 74/254 reads (29%) | catalogued as COSV59695755; called by muse, mutect2, varscan2
- FREM2 | c.7260C>T p.I2420= | Silent (SNP) | VAF 142/367 reads (39%) | called by muse, mutect2, varscan2
- GABPB2 | c.1206C>T p.F402= | Silent (SNP) | VAF 151/668 reads (23%) | called by muse, mutect2, varscan2
- GARNL3 | c.2805G>C p.R935= | Silent (SNP) | VAF 96/396 reads (24%) | called by muse, mutect2, varscan2
- GGNBP2 | c.339C>T p.P113= | Silent (SNP) | VAF 137/456 reads (30%) | called by muse, mutect2, varscan2
- GHR | c.1356G>A p.E452= | Silent (SNP) | VAF 50/225 reads (22%) | catalogued as COSV50119980; called by muse, mutect2, varscan2
- GMIP | c.2643C>T p.T881= | Silent (SNP) | VAF 192/665 reads (29%) | called by muse, mutect2, varscan2
- GNAZ | c.516C>T p.V172= | Silent (SNP) | VAF 82/424 reads (19%) | catalogued as rs758843916; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1116G>A p.E372= | Silent (SNP) | VAF 52/894 reads (6%) | called by muse, mutect2
- GPR137 | c.1119C>A p.P373= | Silent (SNP) | VAF 78/411 reads (19%) | catalogued as COSV100464200; called by muse, mutect2, varscan2
- GPR137C | c.744C>T p.V248= | Silent (SNP) | VAF 57/358 reads (16%) | catalogued as rs1239353914; called by muse, mutect2, varscan2
- GPR152 | c.666C>T p.T222= | Silent (SNP) | VAF 115/555 reads (21%) | called by muse, mutect2, varscan2
- HAO1 | c.951C>T p.I317= | Silent (SNP) | VAF 152/402 reads (38%) | catalogued as rs146949214, COSV66491541, COSV66493536; called by muse, mutect2, varscan2
- HEATR1 | c.4557C>T p.S1519= | Silent (SNP) | VAF 183/386 reads (47%) | called by muse, mutect2, varscan2
- HYDIN | c.7659G>A p.E2553= | Silent (SNP) | VAF 105/522 reads (20%) | called by muse, mutect2, varscan2
- IGHV3-38 | c.108C>T p.S36= | Silent (SNP) | VAF 75/464 reads (16%) | called by muse, mutect2, varscan2
- IL36A | c.54C>T p.I18= | Silent (SNP) | VAF 121/332 reads (36%) | catalogued as COSV52082650; called by muse, mutect2, varscan2
- JAG2 | c.3402C>A p.I1134= | Silent (SNP) | VAF 130/719 reads (18%) | called by muse, mutect2, varscan2
- KCNK10 | c.342G>A p.R114= | Silent (SNP) | VAF 166/514 reads (32%) | called by muse, mutect2, varscan2
- KCNN3 | c.270A>G p.Q90= | Silent (SNP) | VAF 381/832 reads (46%) | called by muse, mutect2, varscan2
- KCNQ3 | c.2557C>T p.L853= | Silent (SNP) | VAF 197/552 reads (36%) | catalogued as COSV101196198; called by muse, mutect2, varscan2
- KIF13B | c.4758G>A p.L1586= | Silent (SNP) | VAF 108/704 reads (15%) | called by muse, mutect2, varscan2
- KIF3B | c.1131G>A p.R377= | Silent (SNP) | VAF 68/442 reads (15%) | catalogued as rs1923098, COSV65229348; called by muse, varscan2
- KIR3DL2 | c.213C>T p.F71= | Silent (SNP) | VAF 64/206 reads (31%) | called by muse, varscan2
- KPNB1 | c.2229C>T p.S743= | Silent (SNP) | VAF 72/265 reads (27%) | called by muse, mutect2, varscan2
- KRTAP10-5 | c.762G>T p.P254= | Silent (SNP) | VAF 82/553 reads (15%) | catalogued as COSV59976516; called by muse, mutect2, varscan2
- LAMC1 | c.3834C>T p.D1278= | Silent (SNP) | VAF 73/361 reads (20%) | called by muse, mutect2, varscan2
- LILRA1 | c.156C>T p.I52= | Silent (SNP) | VAF 136/441 reads (31%) | catalogued as COSV52180980; called by muse, mutect2, varscan2
- LRCOL1 | c.330C>T p.F110= | Silent (SNP) | VAF 153/453 reads (34%) | called by muse, mutect2, varscan2
- LRP5 | c.1191C>T p.I397= | Silent (SNP) | VAF 100/480 reads (21%) | catalogued as rs1246734917, COSV53710879; called by muse, mutect2, varscan2
- LRRC15 | c.1053C>T p.N351= | Silent (SNP) | VAF 114/661 reads (17%) | catalogued as rs148152306; called by muse, mutect2, varscan2
- LRRC4C | c.312C>T p.I104= | Silent (SNP) | VAF 78/399 reads (20%) | catalogued as COSV53423544; called by muse, mutect2, varscan2
- LRRN4 | c.849T>C p.L283= | Silent (SNP) | VAF 45/294 reads (15%) | called by muse, varscan2
- LY9 | c.408G>A p.R136= | Silent (SNP) | VAF 102/437 reads (23%) | catalogued as rs558633490, COSV54431649; called by muse, mutect2, varscan2
- MAP3K11 | c.2184C>T p.P728= | Silent (SNP) | VAF 167/389 reads (43%) | catalogued as rs755382962; called by muse, mutect2, varscan2
- MAP3K4 | c.4410C>T p.F1470= | Silent (SNP) | VAF 78/148 reads (53%) | called by muse, mutect2, varscan2
- MAPK4 | c.1470C>T p.F490= | Silent (SNP) | VAF 77/588 reads (13%) | called by muse, mutect2, varscan2
- MAPT | c.1437G>A p.L479= (on ENST00000262410 / NM_001377265.1; = p.L404= on NM_016835.4) | Silent (SNP) | VAF 195/509 reads (38%) | catalogued as COSV52238898; called by muse, mutect2, varscan2
- MET | c.4102C>T p.L1368= | Silent (SNP) | VAF 147/388 reads (38%) | called by muse, mutect2, varscan2
- MROH2B | c.483C>T p.A161= | Silent (SNP) | VAF 75/242 reads (31%) | called by muse, mutect2, varscan2
- MRPL42 | c.375T>C p.P125= | Silent (SNP) | VAF 90/255 reads (35%) | called by muse, mutect2, varscan2
- MS4A5 | c.96C>T p.T32= | Silent (SNP) | VAF 64/303 reads (21%) | called by muse, mutect2, varscan2
- MYH6 | c.2574C>T p.F858= | Silent (SNP) | VAF 180/568 reads (32%) | catalogued as rs148596692, COSV62455115; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO18B | c.4194C>T p.T1398= | Silent (SNP) | VAF 66/314 reads (21%) | called by muse, mutect2, varscan2
- NPSR1 | c.507C>T p.I169= | Silent (SNP) | VAF 98/324 reads (30%) | catalogued as rs760343674, COSV100706145; called by muse, mutect2
- NRXN1 | c.1947C>T p.I649= | Silent (SNP) | VAF 70/413 reads (17%) | catalogued as rs539484479, COSV58447509; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUP153 | c.1479G>A p.E493= | Silent (SNP) | VAF 78/490 reads (16%) | catalogued as rs1473708858; called by muse, mutect2, varscan2
- NXPE2 | c.564C>T p.S188= | Silent (SNP) | VAF 90/483 reads (19%) | catalogued as COSV100969866; called by muse, mutect2, varscan2
- NXPH1 | c.714C>T p.I238= | Silent (SNP) | VAF 122/387 reads (32%) | catalogued as rs773760900; called by muse, mutect2, varscan2
- OR10G9 | c.87C>T p.F29= | Silent (SNP) | VAF 179/638 reads (28%) | catalogued as rs1452940374; called by muse, mutect2, varscan2
- OR10W1 | c.21C>A p.A7= | Silent (SNP) | VAF 55/281 reads (20%) | called by muse, mutect2, varscan2
- OR2A14 | c.783C>A p.P261= | Silent (SNP) | VAF 64/507 reads (13%) | catalogued as COSV68718451; called by muse, mutect2, varscan2
- OR2AT4 | c.666C>T p.S222= | Silent (SNP) | VAF 106/486 reads (22%) | catalogued as rs868638069, COSV100532417, COSV59407181; called by muse, mutect2, varscan2
- OR5M11 | c.255C>T p.I85= | Silent (SNP) | VAF 67/331 reads (20%) | catalogued as rs748126869, COSV73141645; called by muse, mutect2, varscan2
- OSCAR | c.345C>T p.V115= | Silent (SNP) | VAF 90/468 reads (19%) | called by muse, mutect2, varscan2
- OTOG | c.5169C>T p.P1723= | Silent (SNP) | VAF 79/407 reads (19%) | called by muse, mutect2, varscan2
- PCDH15 | c.5547G>A p.T1849= | Silent (SNP) | VAF 67/246 reads (27%) | catalogued as rs767304005, COSV57343515; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCLO | c.8820C>T p.C2940= | Silent (SNP) | VAF 146/445 reads (33%) | called by muse, varscan2
- PCLO | c.654G>A p.P218= | Silent (SNP) | VAF 92/546 reads (17%) | catalogued as rs1361089909, COSV61618835; called by muse, mutect2, varscan2
- PCP2 | c.375G>A p.R125= | Silent (SNP) | VAF 83/501 reads (17%) | called by muse, mutect2, varscan2
- PDE1B | c.1179C>T p.F393= | Silent (SNP) | VAF 65/288 reads (23%) | called by muse, mutect2, varscan2
- PENK | c.582G>A p.K194= | Silent (SNP) | VAF 87/471 reads (18%) | catalogued as COSV59240172; called by muse, mutect2, varscan2
- PFDN2 | c.354C>T p.F118= | Silent (SNP) | VAF 109/548 reads (20%) | called by muse, mutect2, varscan2
- PLB1 | c.2949C>T p.L983= | Silent (SNP) | VAF 61/288 reads (21%) | called by muse, mutect2, varscan2
- PLCE1 | c.3432C>T p.L1144= | Silent (SNP) | VAF 90/317 reads (28%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.549C>A p.P183= (on ENST00000283426; = p.P539= on NM_052909.5) | Silent (SNP) | VAF 103/408 reads (25%) | catalogued as rs746379606, COSV52047774, COSV52051807; called by muse, mutect2, varscan2
- PNPLA3 | c.1419C>A p.P473= | Silent (SNP) | VAF 49/273 reads (18%) | catalogued as COSV53377381; called by muse, mutect2, varscan2
- POM121L12 | c.315G>A p.E105= | Silent (SNP) | VAF 90/584 reads (15%) | called by muse, mutect2, varscan2
- PPP6R1 | c.2409C>T p.D803= | Silent (SNP) | VAF 147/397 reads (37%) | catalogued as rs1377796526; called by muse, mutect2, varscan2
- PRDM8 | c.423C>T p.C141= | Silent (SNP) | VAF 43/209 reads (21%) | called by muse, mutect2, varscan2
- PRL | c.162C>T p.S54= | Silent (SNP) | VAF 62/404 reads (15%) | catalogued as rs766454499, COSV60592119; called by muse, varscan2
- PRSS58 | c.34C>T p.L12= | Silent (SNP) | VAF 153/449 reads (34%) | called by muse, mutect2, varscan2
- PSMC4 | c.825C>T p.F275= | Silent (SNP) | VAF 72/398 reads (18%) | catalogued as rs1361580117; called by muse, mutect2, varscan2
- RAPSN | c.147G>T p.L49= | Silent (SNP) | VAF 72/386 reads (19%) | called by muse, mutect2, varscan2
- RLN3 | c.309G>A p.G103= | Silent (SNP) | VAF 167/508 reads (33%) | called by muse, mutect2, varscan2
- RP1 | c.840C>A p.T280= | Silent (SNP) | VAF 47/290 reads (16%) | called by muse, mutect2, varscan2
- RXFP3 | c.249C>T p.L83= | Silent (SNP) | VAF 121/458 reads (26%) | catalogued as rs146125808; called by muse, varscan2
- RXFP3 | c.339C>G p.R113= | Silent (SNP) | VAF 97/413 reads (23%) | catalogued as COSV57508661; called by muse, varscan2
- SCN10A | c.732G>A p.K244= | Silent (SNP) | VAF 49/229 reads (21%) | catalogued as COSV71862232; called by muse, mutect2, varscan2
- SCN11A | c.3558C>T p.L1186= | Silent (SNP) | VAF 49/320 reads (15%) | called by muse, mutect2, varscan2
- SDR42E1 | c.852G>A p.L284= | Silent (SNP) | VAF 157/409 reads (38%) | called by muse, mutect2, varscan2
- SELE | c.1827C>T p.I609= | Silent (SNP) | VAF 148/330 reads (45%) | called by muse, mutect2, varscan2
- SH2B2 | c.177C>T p.V59= | Silent (SNP) | VAF 98/683 reads (14%) | called by muse, mutect2, varscan2
- SLC11A1 | c.1449C>T p.F483= | Silent (SNP) | VAF 161/315 reads (51%) | catalogued as rs766975333, COSV51918110; called by muse, varscan2
- SLC25A29 | c.357G>A p.R119= (on ENST00000359232 / NM_001039355.3; = p.R53= on NM_152333.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 215/634 reads (34%) | called by muse, mutect2, varscan2
- SLC2A7 | c.1051C>T p.L351= | Silent (SNP) | VAF 191/322 reads (59%) | called by muse, mutect2, varscan2
- SLC30A8 | c.459G>A p.V153= | Silent (SNP) | VAF 139/435 reads (32%) | called by muse, mutect2, varscan2
- SMAD3 | c.639C>T p.S213= | Silent (SNP) | VAF 115/320 reads (36%) | catalogued as rs768951907; called by muse, mutect2, varscan2
- SPANXD | c.249G>A p.E83= | Silent (SNP) | VAF 81/243 reads (33%) | called by muse, mutect2, varscan2
- SPDYE3 | c.1491G>A p.R497= | Silent (SNP) | VAF 135/382 reads (35%) | called by muse, mutect2, varscan2
- SPG11 | c.2880C>T p.F960= | Silent (SNP) | VAF 72/378 reads (19%) | called by muse, mutect2, varscan2
- SPTB | c.2460C>T p.T820= | Silent (SNP) | VAF 208/630 reads (33%) | catalogued as rs749246537; called by muse, mutect2, varscan2
- SYT7 | c.594C>T p.P198= | Silent (SNP) | VAF 77/344 reads (22%) | catalogued as rs571610142; called by muse, mutect2, varscan2
- TAS2R39 | c.471G>A p.L157= | Silent (SNP) | VAF 159/503 reads (32%) | catalogued as rs766695438, COSV71470930; called by muse, mutect2, varscan2
- TBR1 | c.1740C>A p.P580= | Silent (SNP) | VAF 109/489 reads (22%) | catalogued as rs1298729992; called by muse, mutect2, varscan2
- TBX5 | c.1242C>T p.T414= | Silent (SNP) | VAF 204/579 reads (35%) | catalogued as rs370133092; called by muse, mutect2, varscan2
- TCTN2 | c.75G>A p.G25= | Silent (SNP) | VAF 48/402 reads (12%) | called by muse, mutect2, varscan2
- THAP4 | c.1206C>T p.V402= | Silent (SNP) | VAF 70/301 reads (23%) | called by muse, mutect2, varscan2
- THNSL2 | c.369C>T p.F123= | Silent (SNP) | VAF 77/324 reads (24%) | called by muse, mutect2, varscan2
- THRB | c.147G>A p.L49= | Silent (SNP) | VAF 74/358 reads (21%) | called by muse, mutect2, varscan2
- TLR3 | c.204C>T p.A68= | Silent (SNP) | VAF 88/294 reads (30%) | catalogued as rs201229975, COSV57167280; called by muse, mutect2, varscan2
- TMTC1 | c.1023C>T p.G341= (on ENST00000539277 / NM_001193451.2; = p.G233= on NM_175861.3) | Silent (SNP) | VAF 79/446 reads (18%) | called by muse, mutect2, varscan2
- TMUB2 | c.30C>T p.L10= | Silent (SNP) | VAF 12/414 reads (3%) | catalogued as rs1474881422, COSV60229685; called by muse, mutect2
- TOGARAM2 | c.1206C>T p.P402= | Silent (SNP) | VAF 81/311 reads (26%) | catalogued as rs917671769, COSV65420463; called by muse, mutect2, varscan2
- TPTE | c.300C>T p.F100= (on ENST00000618007 / NM_199261.4; = p.F82= on NM_199259.4) | Silent (SNP) | VAF 74/377 reads (20%) | catalogued as rs1393540247; called by muse, mutect2, varscan2
- TRAJ41 | c.64C>T p.*22= | Silent (SNP) | VAF 102/310 reads (33%) | catalogued as rs753942107; called by muse, mutect2, varscan2
- TRIML2 | c.408G>A p.L136= | Silent (SNP) | VAF 61/336 reads (18%) | catalogued as COSV100456163; called by muse, mutect2, varscan2
- TRPC7 | c.363C>T p.I121= | Silent (SNP) | VAF 302/458 reads (66%) | catalogued as COSV61453869; called by muse, mutect2, varscan2
- TTLL6 | c.1827G>A p.R609= (on ENST00000393382 / NM_001130918.3; = p.R302= on NM_173623.3) | Silent (SNP) | VAF 114/397 reads (29%) | catalogued as COSV64978431; called by muse, mutect2, varscan2
- TUBA3C | c.342C>T p.I114= | Silent (SNP) | VAF 76/356 reads (21%) | catalogued as rs983622040, COSV67138914; called by muse, mutect2, varscan2
- TXNDC11 | c.2574C>T p.A858= (on ENST00000356957 / NM_001303447.2; = p.A831= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 89/467 reads (19%) | catalogued as rs1031836240; called by muse, mutect2, varscan2
- UGT1A7 | c.795G>A p.V265= | Silent (SNP) | VAF 127/230 reads (55%) | catalogued as COSV100692942, COSV60842547; called by muse, mutect2, varscan2
- USHBP1 | c.1431G>A p.L477= | Silent (SNP) | VAF 59/397 reads (15%) | called by muse, mutect2, varscan2
- USP43 | c.1818G>A p.V606= | Silent (SNP) | VAF 70/409 reads (17%) | called by muse, mutect2, varscan2
- USP7 | c.2712G>A p.R904= | Silent (SNP) | VAF 30/197 reads (15%) | called by muse, mutect2, varscan2
- VPS41 | c.408C>T p.F136= | Silent (SNP) | VAF 133/380 reads (35%) | catalogued as rs150900239, COSV56068090; called by muse, mutect2, varscan2
- VSTM4 | c.339C>T p.S113= | Silent (SNP) | VAF 88/315 reads (28%) | catalogued as rs151199777, COSV53677586; called by muse, mutect2, varscan2
- VWDE | c.3291G>A p.V1097= | Silent (SNP) | VAF 98/344 reads (28%) | called by muse, mutect2, varscan2
- VWF | c.255C>T p.S85= | Silent (SNP) | VAF 69/300 reads (23%) | catalogued as rs369017115; called by muse, mutect2, varscan2
- WDR1 | c.1332C>T p.P444= (on ENST00000382452; = p.P304= on NM_005112.5) | Silent (SNP) | VAF 88/384 reads (23%) | catalogued as rs556104463; called by muse, mutect2, varscan2
- WDR62 | c.1800G>T p.G600= | Silent (SNP) | VAF 156/420 reads (37%) | called by muse, mutect2, varscan2
- WDR97 | c.1635C>T p.I545= | Silent (SNP) | VAF 236/630 reads (37%) | called by muse, mutect2, varscan2
- XIRP2 | c.6900G>A p.T2300= (on ENST00000628543; = p.T2475= on NM_152381.6) | Silent (SNP) | VAF 114/388 reads (29%) | catalogued as rs575664263, COSV54699095, COSV54725529; called by muse, mutect2, varscan2
- ZAN | c.1440C>T p.L480= | Silent (SNP) | VAF 190/586 reads (32%) | called by muse, varscan2
- ZCCHC4 | c.12C>T p.S4= | Silent (SNP) | VAF 52/228 reads (23%) | catalogued as COSV57182115; called by muse, mutect2, varscan2
- ZNF155 | c.655C>T p.L219= | Silent (SNP) | VAF 62/364 reads (17%) | catalogued as rs371586040; called by muse, mutect2, varscan2
- ZNF341 | c.2256C>T p.A752= (on ENST00000375200 / NM_001282935.1; = p.A745= on NM_032819.4) | Silent (SNP) | VAF 117/706 reads (17%) | catalogued as COSV100677849, COSV61010957; called by muse, mutect2, varscan2
- ZNF699 | c.1674C>A p.P558= | Silent (SNP) | VAF 54/626 reads (9%) | catalogued as COSV100426837; called by muse, mutect2
- ZNF728 | c.1515G>A p.E505= | Silent (SNP) | VAF 84/385 reads (22%) | called by muse, mutect2, varscan2
- ZRANB3 | c.1695C>T p.I565= | Silent (SNP) | VAF 155/527 reads (29%) | catalogued as rs964573511, COSV51517034; called by muse, mutect2, varscan2
- AC244197.3 | c.*2404C>T | 3'UTR (SNP) | VAF 191/272 reads (70%) | called by muse, mutect2, varscan2
- AREG | c.*59G>A | 3'UTR (SNP) | VAF 58/214 reads (27%) | called by muse, mutect2, varscan2
- ATP6V0A1 | c.-1C>T | 5'UTR (SNP) | VAF 75/227 reads (33%) | catalogued as rs765218836; called by muse, varscan2
- CHRNA3 | chr15:78593157 C>T | 3'Flank (SNP) | VAF 152/336 reads (45%) | catalogued as rs202136309, COSV55137213; called by muse, mutect2, varscan2
- HPS5 | c.3330-627C>T | Intron (SNP) | VAF 106/305 reads (35%) | called by muse, mutect2, varscan2
- ITPRID1 | c.-20+11463C>T | Intron (SNP) | VAF 47/379 reads (12%) | catalogued as rs752191299; called by muse, mutect2, varscan2
- KRBA1 | c.-16G>C | 5'UTR (SNP) | VAF 71/561 reads (13%) | called by muse, mutect2, varscan2
- KRT78 | c.385-101G>A | Intron (SNP) | VAF 125/372 reads (34%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+3465C>T | Intron (SNP) | VAF 32/269 reads (12%) | catalogued as rs1045805744; called by muse, mutect2, varscan2
- MAP4 | c.1999+3464A>T | Intron (SNP) | VAF 32/267 reads (12%) | called by muse, mutect2, varscan2
- METTL15 | c.779-2282C>T | Intron (SNP) | VAF 93/217 reads (43%) | catalogued as COSV100328209; called by muse, mutect2, varscan2
- MGAM | c.4618+13449C>T | Intron (SNP) | VAF 88/577 reads (15%) | called by muse, mutect2, varscan2
- PI4KB | c.-163G>A | 5'UTR (SNP) | VAF 108/371 reads (29%) | called by muse, mutect2, varscan2
- PPP1R14C | c.*487G>A | 3'UTR (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
- REXO1L1P | n.750G>A | RNA (SNP) | VAF 61/922 reads (7%) | catalogued as rs1470324774; called by muse, mutect2
- SEPTIN3 | chr22:41972987 G>A | 5'Flank (SNP) | VAF 77/185 reads (42%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532649 G>A | 5'Flank (SNP) | VAF 245/530 reads (46%) | called by muse, mutect2, varscan2
- TEX101 | c.-22C>T | 5'UTR (SNP) | VAF 52/295 reads (18%) | catalogued as COSV99494766; called by muse, mutect2, varscan2
- TEX101 | c.-21C>T | 5'UTR (SNP) | VAF 53/300 reads (18%) | catalogued as rs1274645237; called by muse, mutect2, varscan2
- THOP1 | c.1908+486C>T | Intron (SNP) | VAF 49/365 reads (13%) | called by muse, mutect2, varscan2
- TNFRSF25 | c.543-9C>T | Intron (SNP) | VAF 110/371 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.34265-5696C>T | Intron (SNP) | VAF 122/349 reads (35%) | catalogued as rs745720476, COSV60064110; called by muse, mutect2, varscan2
- TTN | c.10360+5092G>A | Intron (SNP) | VAF 128/460 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.10360+2050C>T | Intron (SNP) | VAF 54/300 reads (18%) | catalogued as rs771470504, COSV60349815; called by muse, mutect2, varscan2
- ZNF812P | n.1285G>A | RNA (SNP) | VAF 57/466 reads (12%) | catalogued as rs535946176; called by muse, mutect2, varscan2
